Somatic mutation profile of tumor specimen TCGA-2H-A9GM-01A (aliquot TCGA-2H-A9GM-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GM, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 53.3 years (19,484 days).
Specimen TCGA-2H-A9GM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c695b4f-3658-4e88-8f36-6fb3c5d2a673.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GM-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GM-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47f9ead3-140e-4b5b-bb55-d9ac401d299b

The open-access MAF lists 113 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2, RNA 2, Intron 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.526_528dup p.C176dup | In Frame Ins (INS) | VAF 24/37 reads (65%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACSF2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs772568444; called by muse, mutect2, varscan2
- ADGRL2 | c.1383T>G p.I461M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV54684197; called by muse, mutect2, varscan2
- ADORA1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201703869; called by muse, mutect2, varscan2
- AL592490.1 | c.1774A>G p.T592A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs752173190; called by muse, mutect2, varscan2
- AP002512.3 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs758719487, COSV54408487, COSV54409662; called by muse, mutect2, varscan2
- ASTN1 | c.1993C>A p.L665I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1187927015; called by muse, mutect2, varscan2
- ATN1 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV63113206; called by muse, mutect2, varscan2
- C3 | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550043629, CM108969, CM153559; called by muse, mutect2, varscan2
- CNTN3 | c.1250A>C p.K417T | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99726284; called by muse, mutect2, varscan2
- CRISP3 | c.614+1G>A p.X205_splice (on ENST00000371159 / NM_001368123.1; = p.X187_splice on NM_006061.4) | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as rs762333204, COSV53819771, COSV53821819; called by muse, mutect2
- DMD | c.3443G>A p.R1148K | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63732591, COSV63783957; called by muse, mutect2, varscan2
- FARP2 | c.183+1G>T p.X61_splice | Splice Site (SNP) | VAF 23/36 reads (64%) | catalogued as rs1181465869; called by muse, mutect2, varscan2
- FAT2 | c.11284C>T p.R3762W | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs751829289, COSV55823915; called by muse, mutect2, varscan2
- FAT3 | c.8696G>T p.G2899V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1243235866; called by muse, mutect2, varscan2
- GRM3 | c.1073A>T p.K358M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV64472253; called by mutect2, varscan2
- LATS2 | c.1999A>G p.M667V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs145120725; called by mutect2, varscan2
- LRP2 | c.4435C>T p.R1479C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs760099721, COSV55574428; called by muse, mutect2, varscan2
- MUC6 | c.5189C>G p.T1730S | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.914); catalogued as rs575890149; called by muse, mutect2, varscan2
- NDST2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55216073; called by muse, mutect2, varscan2
- OBSCN | c.10067C>T p.T3356I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs527884891; called by mutect2, varscan2
- PCDHB8 | c.903A>C p.E301D | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.232); catalogued as COSV50760370; called by muse, mutect2, varscan2
- PLB1 | c.2959del p.A987Rfs*46 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as COSV59826032; called by mutect2, pindel
- PYROXD2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs199751908; called by muse, mutect2, varscan2
- RCC1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as rs1320135221, COSV65779508; called by muse, mutect2
- SCN7A | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs776957428; called by muse, mutect2, varscan2
- SH2D3C | c.1234G>A p.E412K (on ENST00000314830 / NM_170600.3; = p.E255K on NM_005489.4) | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as rs774083450, COSV59124455; called by muse, mutect2, varscan2
- SLC4A3 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200405778; called by muse, mutect2, varscan2
- SPART | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs776372801; called by muse, mutect2, varscan2
- TLN2 | c.6040G>A p.A2014T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1437262347; called by muse, mutect2, varscan2
- UBR4 | c.2297A>G p.H766R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1475891703; called by mutect2, varscan2
- WFS1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs770713329, COSV99901237; called by mutect2, varscan2
- ZNF790 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV63212328; called by muse, mutect2, varscan2
- ABCA13 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AKAP13 | c.1097A>G p.D366G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATAD3A | c.1233+2T>G p.X411_splice | Splice Site (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- BMP7 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- BOD1L1 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- C1QL3 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH2 | c.1637del p.I546Kfs*4 | Frame Shift Del (DEL) | VAF 23/45 reads (51%) | called by pindel, varscan2
- CDH2 | c.1631T>A p.L544Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- CDH9 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL20A1 | c.1924G>T p.V642L | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DCAF4L1 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2
- EPB41L3 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EVA1A | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT3 | c.5009A>C p.K1670T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- GABRB3 | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFRA1 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- HTR2A | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- INTS3 | c.702C>A p.D234E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIR2DL1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- LILRA1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDFIC | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- NID1 | c.3182C>T p.T1061I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NME5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR8S1 | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OSBPL11 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PCDH10 | c.180G>C p.R60S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2
- PDE10A | c.1235A>T p.K412I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.4183G>T p.A1395S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PIK3C3 | c.621T>G p.S207R | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR16 | c.709C>A p.P237T (on ENST00000407149 / NM_001300783.2; = p.P214T on NM_016644.2) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RREB1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- RTL3 | c.1208A>C p.K403T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3D | c.1960A>C p.S654R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SHROOM4 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SLC35B2 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC37A2 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC7A13 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SLCO1C1 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STRIP2 | c.2465C>T p.S822L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SYTL1 | c.1307C>T p.P436L (on ENST00000543823; = p.P424L on NM_032872.3) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2
- VWA8 | c.4076T>A p.I1359N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- WASF1 | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZFHX4 | c.1742A>G p.D581G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ZFPM2 | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF223 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ZNF43 | c.331A>C p.N111H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZNF681 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ASTN1 | c.2541G>A p.A847= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs778977363, COSV56061983; called by muse, mutect2, varscan2
- ATG9A | c.1317C>T p.R439= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs372559203; called by muse, mutect2, varscan2
- CDC7 | c.36A>G p.P12= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- CFAP47 | c.5202A>G p.K1734= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV100545797; called by muse, mutect2, varscan2
- DAGLB | c.1476G>A p.L492= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- DAPK1 | c.3195C>T p.T1065= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1402695380; called by muse, mutect2, varscan2
- DCAF4L1 | c.1047C>T p.L349= | Silent (SNP) | VAF 41/60 reads (68%) | called by muse, mutect2
- DNAH7 | c.4545G>T p.L1515= | Silent (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- EPHA5 | c.1548G>A p.T516= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs368999628, COSV56671428; called by muse, mutect2, varscan2
- ERC2 | c.981G>A p.E327= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1041074111; called by muse, mutect2, varscan2
- FAXC | c.1077G>T p.L359= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- FCHO2 | c.2151G>A p.T717= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs775181966; called by muse, mutect2, varscan2
- KAT2B | c.885C>T p.C295= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs757161045; called by muse, mutect2, varscan2
- MARS2 | c.1776G>T p.R592= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.20484T>C p.P6828= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- MUC5B | c.2751C>T p.C917= | Silent (SNP) | VAF 46/67 reads (69%) | catalogued as rs745400423, COSV101499969; called by muse, mutect2, varscan2
- OR52A1 | c.411C>A p.I137= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV61092216; called by muse, mutect2, varscan2
- OR5K4 | c.189G>T p.L63= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- OTUD6B | c.372T>C p.I124= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs370719791; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGA3 | c.1770G>A p.K590= | Silent (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- PKHD1 | c.10356T>G p.T3452= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV64398234; called by muse, mutect2, varscan2
- PPEF1 | c.261C>T p.S87= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs769354165; called by muse, mutect2, varscan2
- SPATA31D1 | c.3198A>G p.R1066= | Silent (SNP) | VAF 56/67 reads (84%) | catalogued as rs757155959; called by muse, mutect2, varscan2
- SSTR5 | c.744C>T p.R248= | Silent (SNP) | VAF 53/83 reads (64%) | called by muse, mutect2, varscan2
- TDP1 | c.147C>T p.S49= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs761583949, COSV59641957; called by muse, mutect2, varscan2
- TET3 | c.3666G>A p.P1222= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs143683162; called by muse, mutect2, varscan2
- YIPF2 | c.852G>A p.S284= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as rs940041420; called by muse, mutect2
- ZNF236 | c.1605C>T p.I535= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1299051811; called by muse, mutect2
- AC244258.1 | n.605A>C | RNA (SNP) | VAF 14/42 reads (33%) | catalogued as rs1486827044; called by muse, mutect2, varscan2
- CDH11 | c.1895-609T>G | Intron (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- GABRE | c.784+179T>G | Intron (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1280C>A | RNA (SNP) | VAF 25/212 reads (12%) | called by muse, varscan2
- PAQR6 | c.*241_*242del | 3'UTR (DEL) | VAF 38/83 reads (46%) | called by pindel, varscan2
